Somatic mutation profile of cancer-model specimen HCM-BROD-0353-C64-85A (Adherent Cell Line, passage 13; aliquot HCM-BROD-0353-C64-85A-01D-A88G-36), derived from the primary tumor of HCMI case HCM-BROD-0353-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 14.0 years (5,113 days).
Specimen HCM-BROD-0353-C64-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 13.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d891fa6-9c80-47ba-9e24-cdd85e16793a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0353-C64-11A (Solid Tissue Normal), aliquot HCM-BROD-0353-C64-11A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b371b1d-4ae2-4b0d-912c-752c953711f4

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CMBL | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 99/449 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs753529555, COSV56982833; called by muse, mutect2, varscan2
- OBSCN | c.7265G>T p.G2422V | Missense Mutation (SNP) | VAF 147/712 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs755928557; called by muse, mutect2, varscan2
- PRKG2 | c.131T>A p.I44N | Missense Mutation (SNP) | VAF 90/465 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- RNF213 | c.14836G>T p.E4946* | Nonsense Mutation (SNP) | VAF 21/682 reads (3%) | called by muse, mutect2
- RNF213 | c.14837A>G p.E4946G | Missense Mutation (SNP) | VAF 23/680 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2
- TET3 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 101/556 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
